Somatic mutation profile of tumor specimen ALCH-AEOF-TTR1-A (aliquot ALCH-AEOF-TTR1-A-1-0-D-A85H-36) from ALCHEMIST case ALCH-AEOF, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 54.4 years (19,886 days).
Specimen ALCH-AEOF-TTR1-A: Sample type: FFPE Recurrent; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0e5cf253-49b3-4d3d-bae5-065f68d21a41.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AEOF-NB1-A (Blood Derived Normal), aliquot ALCH-AEOF-NB1-A-1-0-D-A673-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6974214a-f99b-44df-bc4a-e4ee53d32223

The open-access MAF lists 635 somatic variants for this specimen: 472 protein-altering or splice-affecting, 105 silent, 58 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 402, Silent 105, Nonsense Mutation 39, Intron 30, Splice Site 16, 5'UTR 10, RNA 8, Frame Shift Del 7, 3'UTR 5, Frame Shift Ins 3, 5'Flank 3, Splice Region 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL17A1 | c.3156C>T p.G1052= | Silent (SNP) | VAF 67/393 reads (17%) | catalogued as rs760714959, CS152543; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KMT2D | c.5104C>T p.R1702* | Nonsense Mutation (SNP) | VAF 17/333 reads (5%) | catalogued as rs886043414, COSV56407907; ClinVar: pathogenic; called by muse, mutect2
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 76/404 reads (19%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.469G>T p.V157F | Missense Mutation (SNP) | VAF 25/117 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912654, CM137621, COSV52667015, COSV52676009, COSV52752314, COSV53205488; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADGRL3 | c.56-1G>T p.X19_splice | Splice Site (SNP) | VAF 9/121 reads (7%) | catalogued as COSV101547475; called by muse, mutect2
- ALG13 | c.2090G>A p.R697H | Missense Mutation (SNP) | VAF 34/212 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as rs1416055334, COSV52635322; called by muse, mutect2, varscan2
- AMER2 | c.1069C>A p.P357T | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as COSV63438863; called by muse, mutect2, varscan2
- AMPH | c.1096G>T p.A366S | Missense Mutation (SNP) | VAF 153/489 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as rs769186615; called by muse, mutect2, varscan2
- AP001781.2 | c.64G>T p.E22* | Nonsense Mutation (SNP) | VAF 23/150 reads (15%) | catalogued as COSV99499532; called by muse, mutect2, varscan2
- APCS | c.318G>T p.K106N | Missense Mutation (SNP) | VAF 51/203 reads (25%) | SIFT tolerated (0.6); PolyPhen benign (0.005); catalogued as COSV99661220; called by muse, mutect2, varscan2
- ARHGAP31 | c.232G>T p.D78Y | Missense Mutation (SNP) | VAF 126/520 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1247569081; called by muse, mutect2, varscan2
- ARHGAP33 | c.3236C>G p.P1079R | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.178); catalogued as COSV99137389; called by muse, mutect2
- ASXL3 | c.661C>G p.P221A | Missense Mutation (SNP) | VAF 22/262 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.996); catalogued as COSV52457906; called by muse, mutect2
- ATP11C | c.2870G>T p.G957V | Missense Mutation (SNP) | VAF 22/230 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.322); catalogued as COSV59566532; called by muse, mutect2
- ATP6V0A2 | c.2560A>T p.S854C | Missense Mutation (SNP) | VAF 101/317 reads (32%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.122); catalogued as rs773898986; called by muse, mutect2, varscan2
- BBS9 | c.2020C>T p.R674W (on ENST00000242067 / NM_001348036.1; = p.R634W on NM_014451.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 51/838 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs368526968; called by muse, mutect2
- BCHE | c.656G>A p.S219N | Missense Mutation (SNP) | VAF 30/198 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.158); catalogued as rs1367718556; called by muse, mutect2, varscan2
- BLK | c.547G>T p.D183Y | Missense Mutation (SNP) | VAF 30/173 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52053553; called by muse, mutect2, varscan2
- C12orf56 | c.1584+1G>A p.X528_splice (on ENST00000543942 / NM_001170633.2; = p.X368_splice on NM_001099676.3) | Splice Site (SNP) | VAF 13/192 reads (7%) | catalogued as rs750571502, COSV61490473; called by muse, mutect2
- CADM3 | c.150C>A p.C50* (on ENST00000368125 / NM_001127173.3; = p.C84* on NM_021189.5) | Nonsense Mutation (SNP) | VAF 69/382 reads (18%) | catalogued as COSV63683592; called by muse, mutect2, varscan2
- CASS4 | c.1348A>T p.K450* | Nonsense Mutation (SNP) | VAF 16/76 reads (21%) | catalogued as COSV100824749; called by muse, mutect2, varscan2
- CCDC137 | c.775G>T p.V259L | Missense Mutation (SNP) | VAF 13/232 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.114); catalogued as COSV61303773; called by muse, mutect2
- CCSER2 | c.1691C>T p.A564V | Missense Mutation (SNP) | VAF 25/196 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as rs201743744; called by muse, mutect2, varscan2
- CD44 | c.136C>G p.R46G | Missense Mutation (SNP) | VAF 44/270 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.332); catalogued as rs121909545, COSV53536915; called by muse, mutect2, varscan2
- CDH24 | c.2068G>A p.G690S | Missense Mutation (SNP) | VAF 42/298 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57458675; called by muse, mutect2, varscan2
- CDH7 | c.1718G>A p.S573N | Missense Mutation (SNP) | VAF 32/452 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1199155188; called by muse, mutect2
- CHSY1 | c.576G>T p.E192D | Missense Mutation (SNP) | VAF 42/315 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as rs148344653; called by muse, mutect2, varscan2
- CLSPN | c.1873G>A p.E625K | Missense Mutation (SNP) | VAF 77/492 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV52057311; called by muse, mutect2, varscan2
- CNGB3 | c.2288T>A p.V763E | Missense Mutation (SNP) | VAF 42/520 reads (8%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV100183335; called by muse, mutect2
- COL11A1 | c.274+1G>T p.X92_splice | Splice Site (SNP) | VAF 42/236 reads (18%) | catalogued as COSV62174701; called by muse, varscan2
- COL11A1 | c.154G>T p.E52* | Nonsense Mutation (SNP) | VAF 28/158 reads (18%) | catalogued as COSV100615367, COSV62195294; called by muse, varscan2
- COL4A5 | c.4325G>T p.G1442V | Missense Mutation (SNP) | VAF 33/256 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM094057, CM990411; called by muse, mutect2, varscan2
- COL5A3 | c.5096G>A p.R1699Q | Missense Mutation (SNP) | VAF 17/130 reads (13%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.968); catalogued as rs370271810; called by muse, mutect2, varscan2
- CPED1 | c.790C>T p.R264* | Nonsense Mutation (SNP) | VAF 71/286 reads (25%) | catalogued as rs200483154; called by muse, mutect2, varscan2
- CRTAM | c.838G>A p.G280R | Missense Mutation (SNP) | VAF 19/224 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as rs767546285; called by muse, mutect2
- CSH1 | c.631G>T p.V211L | Missense Mutation (SNP) | VAF 44/401 reads (11%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.907); catalogued as rs766343963, COSV100298405, COSV60242550; called by muse, mutect2, varscan2
- CSMD3 | c.4736C>A p.P1579H (on ENST00000297405 / NM_001363185.1; = p.P1475H on NM_052900.3) | Missense Mutation (SNP) | VAF 335/609 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV52198184, COSV52274800; called by muse, mutect2, varscan2
- CSMD3 | c.685G>T p.D229Y | Missense Mutation (SNP) | VAF 410/778 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52149077; called by muse, mutect2, varscan2
- CUBN | c.4351-1G>T p.X1451_splice | Splice Site (SNP) | VAF 82/380 reads (22%) | catalogued as COSV100912592; called by muse, mutect2, varscan2
- DACT1 | c.1982G>T p.G661V | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.812); catalogued as COSV60021569; called by muse, mutect2, varscan2
- DCAF12L1 | c.740C>A p.P247Q | Missense Mutation (SNP) | VAF 67/209 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV64421193; called by muse, mutect2, varscan2
- DCC | c.3922C>A p.Q1308K | Missense Mutation (SNP) | VAF 66/356 reads (19%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.593); catalogued as COSV101473539; called by muse, mutect2, varscan2
- DCSTAMP | c.1030-1G>C p.X344_splice | Splice Site (SNP) | VAF 17/87 reads (20%) | catalogued as COSV99887112; called by muse, mutect2, varscan2
- DEFB113 | c.89A>G p.E30G | Missense Mutation (SNP) | VAF 24/219 reads (11%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); catalogued as rs1475199076; called by muse, mutect2, varscan2
- DIAPH3 | c.1352A>G p.Y451C (on ENST00000400324 / NM_001042517.2; = p.Y188C on NM_030932.3) | Missense Mutation (SNP) | VAF 21/156 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs1204841723; called by muse, mutect2, varscan2
- DSE | c.1978G>T p.A660S | Missense Mutation (SNP) | VAF 61/238 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as COSV99045278; called by muse, mutect2, varscan2
- DYNC2I1 | c.1126G>T p.D376Y | Missense Mutation (SNP) | VAF 57/249 reads (23%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.831); catalogued as COSV68104153; called by muse, mutect2, varscan2
- EDIL3 | c.651G>T p.Q217H | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56878031; called by mutect2, varscan2
- EFTUD2 | c.502A>G p.T168A | Missense Mutation (SNP) | VAF 17/252 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.113); catalogued as rs752672329, COSV68184146; called by muse, mutect2
- ELAVL4 | c.509G>T p.G170V | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1427053388, COSV63916082; called by muse, mutect2
- ELMO1 | c.1663C>T p.R555C | Missense Mutation (SNP) | VAF 83/535 reads (16%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.931); catalogued as rs776394175, COSV60297388, COSV60304608; called by muse, mutect2, varscan2
- ENPP7 | c.68C>A p.P23Q | Missense Mutation (SNP) | VAF 84/197 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV60385748; called by muse, mutect2, varscan2
- ESRRG | c.1237C>G p.R413G | Missense Mutation (SNP) | VAF 75/423 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63161834; called by muse, mutect2, varscan2
- FANCM | c.3622G>T p.G1208C | Missense Mutation (SNP) | VAF 43/267 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as COSV57497409; called by muse, mutect2, varscan2
- FAT3 | c.11811C>G p.Y3937* | Nonsense Mutation (SNP) | VAF 32/196 reads (16%) | catalogued as COSV53138041; called by muse, mutect2, varscan2
- FGF5 | c.574C>A p.L192M | Missense Mutation (SNP) | VAF 76/252 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56891732; called by muse, mutect2, varscan2
- GABRG1 | c.987T>A p.Y329* | Nonsense Mutation (SNP) | VAF 31/313 reads (10%) | catalogued as COSV99777484; called by muse, mutect2, varscan2
- GBE1 | c.1802A>G p.Q601R | Missense Mutation (SNP) | VAF 59/259 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.147); catalogued as rs1215596601; called by muse, mutect2, varscan2
- GHDC | c.123G>T p.W41C | Missense Mutation (SNP) | VAF 58/288 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV56987490; called by muse, varscan2
- GHSR | c.224G>T p.R75L | Missense Mutation (SNP) | VAF 108/399 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53837321; called by muse, mutect2, varscan2
- GLYCTK | c.1045G>A p.G349R | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as rs370096769; called by muse, mutect2, varscan2
- H3C11 | c.10A>G p.T4A | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); catalogued as COSV58899358; called by muse, mutect2, varscan2
- HCN1 | c.1022G>T p.W341L | Missense Mutation (SNP) | VAF 22/728 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.262); catalogued as COSV57490864; called by muse, mutect2
- HIVEP1 | c.8084G>A p.R2695Q | Missense Mutation (SNP) | VAF 40/209 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.027); catalogued as rs1475339408, COSV101045708; called by muse, mutect2, varscan2
- HLA-C | c.824C>T p.S275F | Missense Mutation (SNP) | VAF 36/178 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV66115079; called by muse, varscan2
- IGKV1-16 | c.245C>T p.S82L | Missense Mutation (SNP) | VAF 56/531 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.165); catalogued as rs781184992; called by muse, mutect2, varscan2
- INO80 | c.2958G>T p.Q986H | Missense Mutation (SNP) | VAF 26/253 reads (10%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs758299239; called by muse, mutect2, varscan2
- IQCF5 | c.235C>T p.R79C | Missense Mutation (SNP) | VAF 76/294 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.741); catalogued as rs913806331, COSV71306898; called by muse, mutect2, varscan2
- ITGBL1 | c.656A>G p.Q219R | Missense Mutation (SNP) | VAF 25/296 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs920780629; called by muse, mutect2
- JPH1 | c.1013G>A p.R338H | Missense Mutation (SNP) | VAF 33/928 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as rs1290300135, COSV60609171; called by muse, mutect2
- KAT2A | c.2041C>T p.R681C | Missense Mutation (SNP) | VAF 43/173 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs199513433; called by muse, mutect2, varscan2
- KCNT2 | c.3278T>C p.I1093T | Missense Mutation (SNP) | VAF 71/257 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as COSV99655358; called by muse, mutect2, varscan2
- KIAA0753 | c.722G>T p.R241I | Missense Mutation (SNP) | VAF 59/188 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.568); catalogued as COSV63818941; called by muse, mutect2, varscan2
- KLHL13 | c.944C>A p.A315D | Missense Mutation (SNP) | VAF 110/466 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV53247888; called by muse, mutect2, varscan2
- KRTAP19-5 | c.46G>A p.G16R | Missense Mutation (SNP) | VAF 48/369 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.118); catalogued as rs770493303, COSV61858950; called by muse, mutect2, varscan2
- LILRB2 | c.1405G>T p.V469F | Missense Mutation (SNP) | VAF 28/264 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV58746947; called by muse, varscan2
- LRP1B | c.822G>A p.W274* | Nonsense Mutation (SNP) | VAF 76/255 reads (30%) | catalogued as COSV101262157; called by muse, mutect2, varscan2
- LRRTM4 | c.185G>T p.G62V | Missense Mutation (SNP) | VAF 77/360 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.934); catalogued as rs1181915406, COSV69139030, COSV69142914; called by muse, mutect2, varscan2
- LYPD2 | c.191A>G p.Q64R | Missense Mutation (SNP) | VAF 21/291 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs1328892129; called by muse, mutect2
- MAOB | c.281G>A p.G94D | Missense Mutation (SNP) | VAF 18/145 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs1423670702, COSV65204578; called by muse, mutect2, varscan2
- MC3R | c.537C>A p.F179L | Missense Mutation (SNP) | VAF 58/446 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs1568966470; called by muse, mutect2, varscan2
- MED17 | c.1526del p.G509Efs*3 | Frame Shift Del (DEL) | VAF 46/404 reads (11%) | catalogued as rs1234776484; called by mutect2, pindel, varscan2
- MIA3 | c.3682A>G p.T1228A | Missense Mutation (SNP) | VAF 42/254 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1450776972; called by muse, mutect2, varscan2
- MRC2 | c.4147G>T p.A1383S | Missense Mutation (SNP) | VAF 70/199 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV57641673, COSV57645123; called by muse, mutect2, varscan2
- MYF5 | c.278G>C p.R93P | Missense Mutation (SNP) | VAF 126/339 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57356615; called by muse, mutect2, varscan2
- MYH7B | c.2458G>A p.V820I | Missense Mutation (SNP) | VAF 53/307 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs376856126; called by muse, mutect2, varscan2
- MYLK | c.3329C>T p.A1110V | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.154); catalogued as rs1262789998; called by muse, mutect2, varscan2
- MYLK4 | c.739G>T p.D247Y | Missense Mutation (SNP) | VAF 40/191 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1391037353; called by muse, mutect2, varscan2
- NHSL2 | c.220C>A p.R74S | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.045); catalogued as rs946275942; called by muse, mutect2, varscan2
- NLRP3 | c.2827G>T p.V943L | Missense Mutation (SNP) | VAF 72/386 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs199878892; called by muse, mutect2, varscan2
- NOTCH4 | c.4198C>G p.R1400G | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.29); catalogued as COSV66678499; called by muse, mutect2, varscan2
- NPAP1 | c.1798C>A p.L600I | Missense Mutation (SNP) | VAF 36/180 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.266); catalogued as COSV61505094, COSV61509813; called by muse, mutect2, varscan2
- NRXN2 | c.4523C>A p.T1508K | Missense Mutation (SNP) | VAF 28/137 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as COSV99632381; called by muse, mutect2, varscan2
- NUP210 | c.5393G>C p.S1798T | Missense Mutation (SNP) | VAF 48/205 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV54403170; called by muse, mutect2, varscan2
- OGDH | c.3072G>T p.*1024Yext*25 | Nonstop Mutation (SNP) | VAF 13/151 reads (9%) | catalogued as COSV99759757; called by muse, mutect2
- OR11A1 | c.367C>A p.R123S | Missense Mutation (SNP) | VAF 25/136 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs373751127; called by muse, mutect2, varscan2
- OR5AC2 | c.341G>T p.C114F | Missense Mutation (SNP) | VAF 64/312 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); catalogued as COSV100684323; called by muse, mutect2, varscan2
- OR8I2 | c.778C>G p.Q260E | Missense Mutation (SNP) | VAF 26/165 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.22); catalogued as COSV100136218; called by muse, mutect2, varscan2
- OSBPL10 | c.1758G>T p.E586D | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.17); catalogued as COSV67340259; called by muse, mutect2, varscan2
- OVCH1 | c.1219G>A p.V407I | Missense Mutation (SNP) | VAF 28/342 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs180973595; called by muse, mutect2
- PCDH15 | c.5051C>A p.A1684E (on ENST00000644397 / NM_001354429.2; = p.A1626E on NM_001142771.2) | Missense Mutation (SNP) | VAF 223/781 reads (29%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.215); catalogued as rs752801351, COSV100905466; called by muse, mutect2, varscan2
- PCDH15 | c.4854G>T p.E1618D | Missense Mutation (SNP) | VAF 26/546 reads (5%) | SIFT deleterious, low confidence (0.02); catalogued as rs531574437, COSV64682261; called by muse, mutect2
- PCDHA3 | c.2321C>A p.P774H | Missense Mutation (SNP) | VAF 84/257 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV63541409; called by muse, mutect2, varscan2
- PDE2A | c.1700C>G p.A567G | Missense Mutation (SNP) | VAF 53/246 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.52); catalogued as COSV57803429; called by muse, mutect2, varscan2
- PDE6H | c.40C>A p.Q14K | Missense Mutation (SNP) | VAF 142/424 reads (33%) | SIFT tolerated, low confidence (0.89); PolyPhen benign (0.085); catalogued as COSV99844102; called by muse, mutect2, varscan2
- PLD4 | c.397G>C p.V133L | Missense Mutation (SNP) | VAF 12/151 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0.011); catalogued as COSV66915520; called by muse, mutect2
- PLEC | c.5683G>A p.A1895T (on ENST00000322810 / NM_201380.4; = p.A1785T on NM_000445.5) | Missense Mutation (SNP) | VAF 36/555 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.707); catalogued as rs1231630450; called by muse, mutect2
- PLEKHG5 | c.1015G>T p.E339* (on ENST00000400915 / NM_001042663.3; = p.E302* on NM_020631.6) | Nonsense Mutation (SNP) | VAF 96/423 reads (23%) | catalogued as COSV100556170, COSV61702357; called by muse, mutect2, varscan2
- PLG | c.528C>A p.C176* | Nonsense Mutation (SNP) | VAF 94/387 reads (24%) | catalogued as rs558599800, COSV51984719; called by muse, mutect2, varscan2
- PLP1 | c.543G>C p.W181C | Missense Mutation (SNP) | VAF 174/637 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM002828, COSV58276060; called by muse, mutect2, varscan2
- POTEC | c.196C>A p.H66N | Missense Mutation (SNP) | VAF 23/302 reads (8%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0.049); catalogued as COSV100743277; called by muse, mutect2
- POTEM | c.950C>A p.S317* | Nonsense Mutation (SNP) | VAF 57/314 reads (18%) | catalogued as COSV101193836; called by muse, mutect2, varscan2
- PRND | c.9G>T p.K3N | Missense Mutation (SNP) | VAF 50/325 reads (15%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.006); catalogued as rs768711861; called by muse, mutect2, varscan2
- PROS1 | c.1681C>T p.R561W | Missense Mutation (SNP) | VAF 58/238 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.88); catalogued as rs121918476, CM057362, CM991071; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RADIL | c.626C>A p.P209H | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV101271190; called by muse, mutect2, varscan2
- RANBP2 | c.5298G>T p.E1766D | Missense Mutation (SNP) | VAF 91/326 reads (28%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0); catalogued as rs140653325; called by muse, mutect2, varscan2
- RBM19 | c.1811A>C p.Q604P | Missense Mutation (SNP) | VAF 44/154 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.503); catalogued as rs990557322; called by muse, mutect2, varscan2
- RGR | c.684G>T p.W228C | Missense Mutation (SNP) | VAF 161/503 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1212697754, COSV100812953; called by muse, mutect2, varscan2
- RNF31 | c.2708A>G p.N903S | Missense Mutation (SNP) | VAF 13/174 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs770464670; called by muse, mutect2
- RTN1 | c.308C>A p.S103* | Nonsense Mutation (SNP) | VAF 23/101 reads (23%) | catalogued as COSV50718708; called by muse, mutect2, varscan2
- RYR1 | c.13187C>T p.P4396L | Missense Mutation (SNP) | VAF 18/152 reads (12%) | SIFT tolerated (0.43); PolyPhen benign (0.005); catalogued as rs1444540296; called by muse, mutect2, varscan2
- SCAPER | c.2030A>G p.K677R | Missense Mutation (SNP) | VAF 28/128 reads (22%) | SIFT tolerated (0.77); PolyPhen benign (0.178); catalogued as rs1160566430; called by muse, mutect2, varscan2
- SEC31A | c.3086G>T p.G1029V (on ENST00000355196 / NM_001318120.1; = p.G990V on NM_016211.4) | Missense Mutation (SNP) | VAF 44/331 reads (13%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.548); catalogued as COSV52341470; called by muse, mutect2, varscan2
- SHOX | c.596A>G p.Y199C | Missense Mutation (SNP) | VAF 79/485 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1309060961; called by muse, mutect2, varscan2
- SKIDA1 | c.2597C>A p.P866Q | Missense Mutation (SNP) | VAF 38/316 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71610808; called by mutect2, varscan2
- SMARCAD1 | c.1651G>A p.V551I | Missense Mutation (SNP) | VAF 99/519 reads (19%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.693); catalogued as rs925841496; called by muse, mutect2, varscan2
- SMARCD2 | c.10C>T p.R4* | Nonsense Mutation (SNP) | VAF 26/74 reads (35%) | catalogued as rs1251719291; called by muse, mutect2, varscan2
- SNAPC1 | c.788C>T p.A263V | Missense Mutation (SNP) | VAF 18/192 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs762346560; called by muse, mutect2, varscan2
- SOGA1 | c.1454G>T p.G485V | Missense Mutation (SNP) | VAF 43/194 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.055); catalogued as rs751198117, COSV99413027; called by muse, mutect2, varscan2
- SORBS2 | c.997G>A p.D333N | Missense Mutation (SNP) | VAF 23/214 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.253); catalogued as rs1214627955; called by muse, mutect2, varscan2
- SPANXN3 | c.269A>G p.D90G | Missense Mutation (SNP) | VAF 14/336 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV65140187; called by muse, mutect2
- STAC | c.199G>T p.E67* | Nonsense Mutation (SNP) | VAF 22/466 reads (5%) | catalogued as COSV56206657; called by muse, mutect2
- STAM | c.1327G>C p.V443L | Missense Mutation (SNP) | VAF 28/158 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs782429739; called by muse, mutect2, varscan2
- STOML3 | c.31C>A p.Q11K | Missense Mutation (SNP) | VAF 21/153 reads (14%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs147878470, COSV65512160; called by muse, mutect2, varscan2
- TANC2 | c.3226C>T p.R1076C | Missense Mutation (SNP) | VAF 37/110 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs368122235, COSV67329949; called by muse, mutect2, varscan2
- TCHH | c.4625G>A p.R1542H | Missense Mutation (SNP) | VAF 85/343 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.662); catalogued as rs548533493; called by muse, mutect2, varscan2
- TEX11 | c.2366C>G p.P789R (on ENST00000344304; = p.P774R on NM_031276.3) | Missense Mutation (SNP) | VAF 19/186 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100721426; called by muse, mutect2
- TEX13C | c.2847G>T p.K949N | Missense Mutation (SNP) | VAF 36/483 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs1355402058; called by muse, mutect2
- TGIF2LX | c.536C>T p.P179L | Missense Mutation (SNP) | VAF 66/494 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); catalogued as rs753807305, COSV99383532; called by muse, mutect2, varscan2
- TLL1 | c.449C>T p.T150I | Missense Mutation (SNP) | VAF 60/380 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50305017; called by muse, mutect2, varscan2
- TLL1 | c.967C>G p.R323G | Missense Mutation (SNP) | VAF 173/550 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV50342931; called by muse, mutect2, varscan2
- TMEM151A | c.686C>T p.A229V | Missense Mutation (SNP) | VAF 9/119 reads (8%) | SIFT tolerated (0.83); PolyPhen benign (0.015); catalogued as COSV59173456; called by muse, mutect2
- TMEM63C | c.222C>A p.H74Q | Missense Mutation (SNP) | VAF 22/138 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.166); catalogued as rs751143240; called by muse, mutect2, varscan2
- TMPRSS11A | c.239C>T p.T80M | Missense Mutation (SNP) | VAF 18/205 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs187902089; called by muse, mutect2
- TNR | c.2704C>A p.Q902K | Missense Mutation (SNP) | VAF 23/146 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV54898609; called by muse, mutect2, varscan2
- TRIM21 | c.1328G>T p.R443L | Missense Mutation (SNP) | VAF 37/263 reads (14%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.88); catalogued as COSV54345244; called by muse, mutect2, varscan2
- TRIM50 | c.858C>A p.F286L | Missense Mutation (SNP) | VAF 36/170 reads (21%) | SIFT tolerated (0.6); PolyPhen benign (0.173); catalogued as COSV60793682, COSV60795944; called by muse, mutect2, varscan2
- TSKU | c.469G>A p.G157S | Missense Mutation (SNP) | VAF 28/174 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.434); catalogued as rs1463228408; called by muse, mutect2, varscan2
- URI1 | c.136G>T p.E46* | Nonsense Mutation (SNP) | VAF 44/302 reads (15%) | catalogued as COSV100369017; called by muse, mutect2, varscan2
- VRTN | c.643C>A p.P215T | Missense Mutation (SNP) | VAF 30/138 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0.01); catalogued as COSV56440426; called by muse, mutect2, varscan2
- ZNF200 | c.67C>G p.P23A | Missense Mutation (SNP) | VAF 9/210 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.079); catalogued as COSV67723541; called by muse, mutect2
- ZNF227 | c.2212C>T p.H738Y | Missense Mutation (SNP) | VAF 23/163 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57311803; called by muse, mutect2, varscan2
- ZNF267 | c.1715G>T p.G572V | Missense Mutation (SNP) | VAF 54/233 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV100339553; called by muse, mutect2, varscan2
- ZNF446 | c.1202G>A p.G401E | Missense Mutation (SNP) | VAF 46/176 reads (26%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.934); catalogued as rs773922865; called by muse, mutect2, varscan2
- ZNF479 | c.163C>A p.L55M | Missense Mutation (SNP) | VAF 69/423 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58638045; called by muse, mutect2, varscan2
- ZNF521 | c.2563G>T p.E855* | Nonsense Mutation (SNP) | VAF 25/256 reads (10%) | catalogued as COSV64126122; called by muse, mutect2, varscan2
- ZNF560 | c.910C>A p.Q304K | Missense Mutation (SNP) | VAF 84/329 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.074); catalogued as COSV56867231; called by muse, mutect2, varscan2
- ZNF786 | c.1138A>T p.M380L | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV60275801; called by muse, mutect2, varscan2
- ZP4 | c.316C>A p.P106T | Missense Mutation (SNP) | VAF 54/354 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs1463718443; called by muse, mutect2, varscan2
- ZSCAN10 | c.1934G>T p.R645L (on ENST00000252463; = p.R700L on NM_032805.3) | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV52970923; called by muse, mutect2, varscan2
- ABCA2 | c.2165A>T p.Y722F (on ENST00000614293; = p.Y692F on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.377); called by muse, varscan2
- ABCA8 | c.4156-1G>T p.X1386_splice | Splice Site (SNP) | VAF 98/252 reads (39%) | called by muse, mutect2, varscan2
- ABCA9 | c.2123G>T p.G708V | Missense Mutation (SNP) | VAF 81/274 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ABCB5 | c.3424C>G p.P1142A (on ENST00000404938 / NM_001163941.2; = p.P697A on NM_178559.6) | Missense Mutation (SNP) | VAF 103/255 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- ABLIM1 | c.449A>T p.Y150F | Missense Mutation (SNP) | VAF 84/255 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- ACAP2 | c.2118A>T p.E706D | Missense Mutation (SNP) | VAF 78/347 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ACLY | c.236A>T p.D79V | Missense Mutation (SNP) | VAF 17/272 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.201); called by muse, mutect2
- ACTA1 | c.457A>T p.I153F | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- ADAMTS20 | c.328G>T p.G110* | Nonsense Mutation (SNP) | VAF 73/204 reads (36%) | called by muse, mutect2, varscan2
- ADAMTSL1 | c.2391G>A p.W797* | Nonsense Mutation (SNP) | VAF 23/113 reads (20%) | called by muse, mutect2
- ADAMTSL1 | c.5064G>T p.Q1688H | Missense Mutation (SNP) | VAF 27/341 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- ADCY7 | c.1748G>T p.R583L | Missense Mutation (SNP) | VAF 29/219 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- ADGRA1 | c.1256G>T p.G419V | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- ADGRG1 | c.266A>T p.H89L | Missense Mutation (SNP) | VAF 153/583 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- ADGRG4 | c.6835T>A p.F2279I | Missense Mutation (SNP) | VAF 26/292 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ADGRL4 | c.1921G>T p.A641S | Missense Mutation (SNP) | VAF 37/336 reads (11%) | SIFT tolerated (0.71); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- AHNAK2 | c.10921C>A p.P3641T | Missense Mutation (SNP) | VAF 65/354 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- AK8 | c.190G>T p.G64C | Missense Mutation (SNP) | VAF 38/224 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- AKAP11 | c.2353G>T p.A785S | Missense Mutation (SNP) | VAF 16/143 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- AKNAD1 | c.418G>T p.D140Y | Missense Mutation (SNP) | VAF 38/147 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ALG13 | c.2821C>A p.P941T | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT tolerated (0.39); PolyPhen benign (0.102); called by muse, varscan2
- ALKBH1 | c.1031G>T p.R344L | Missense Mutation (SNP) | VAF 56/435 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- ALMS1 | c.2428G>C p.A810P | Missense Mutation (SNP) | VAF 84/390 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ANK2 | c.4248+2T>A p.X1416_splice | Splice Site (SNP) | VAF 60/228 reads (26%) | called by muse, mutect2, varscan2
- ANKRD17 | c.6460C>T p.P2154S | Missense Mutation (SNP) | VAF 24/236 reads (10%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- ANKRD36 | c.2479G>T p.A827S | Missense Mutation (SNP) | VAF 70/451 reads (16%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ANO7 | c.254C>G p.T85R (on ENST00000274979; = p.T31R on NM_001001666.4) | Missense Mutation (SNP) | VAF 9/113 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.266); called by muse, mutect2
- ANTKMT | c.352G>T p.A118S | Missense Mutation (SNP) | VAF 17/150 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- APOBEC3A | c.388T>A p.Y130N | Missense Mutation (SNP) | VAF 40/178 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- ARHGEF18 | c.2423G>T p.R808L (on ENST00000359920 / NM_001130955.2; = p.R704L on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 55/311 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- ARHGEF2 | c.2872C>G p.P958A (on ENST00000361247 / NM_001162383.2; = p.P930A on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 48/189 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.681); called by muse, mutect2, varscan2
- ASIC5 | c.168C>G p.N56K | Missense Mutation (SNP) | VAF 63/477 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- ASTN2 | c.1272C>A p.S424R (on ENST00000313400 / NM_001365069.1; = p.S373R on NM_014010.5) | Missense Mutation (SNP) | VAF 40/153 reads (26%) | SIFT tolerated, low confidence (0.63); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- ASXL3 | c.2261C>T p.P754L | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.274); called by muse, mutect2
- ATAD2B | c.1180G>A p.D394N | Missense Mutation (SNP) | VAF 51/284 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATF7IP | c.3178C>T p.H1060Y | Missense Mutation (SNP) | VAF 32/421 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.558); called by muse, mutect2
- ATP10D | c.982C>G p.L328V | Missense Mutation (SNP) | VAF 40/248 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- ATXN3 | c.1088C>T p.P363L | Missense Mutation (SNP) | VAF 31/122 reads (25%) | PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- BEND3 | c.1126G>T p.E376* | Nonsense Mutation (SNP) | VAF 33/113 reads (29%) | called by muse, mutect2, varscan2
- BPIFB6 | c.796G>T p.E266* | Nonsense Mutation (SNP) | VAF 83/317 reads (26%) | called by muse, mutect2, varscan2
- BRWD3 | c.3337G>T p.D1113Y | Missense Mutation (SNP) | VAF 61/496 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- BTK | c.1018C>A p.P340T | Missense Mutation (SNP) | VAF 78/565 reads (14%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.572); called by muse, mutect2, varscan2
- C8A | c.61C>A p.Q21K | Missense Mutation (SNP) | VAF 119/712 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- CACNA1D | c.283G>T p.G95C | Missense Mutation (SNP) | VAF 79/465 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- CAMK4 | c.1294C>A p.L432I | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC110 | c.1807G>T p.G603* | Nonsense Mutation (SNP) | VAF 46/174 reads (26%) | called by muse, varscan2
- CCDC110 | c.1744C>A p.Q582K | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.337); called by muse, varscan2
- CCDC168 | c.18138T>A p.N6046K | Missense Mutation (SNP) | VAF 50/410 reads (12%) | SIFT tolerated (0.83); PolyPhen benign (0.445); called by muse, mutect2, varscan2
- CCDC168 | c.6169G>A p.G2057R | Missense Mutation (SNP) | VAF 11/139 reads (8%) | SIFT tolerated (0.76); PolyPhen benign (0.007); called by muse, mutect2
- CCDC178 | c.1201G>C p.D401H | Missense Mutation (SNP) | VAF 9/162 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- CCDC191 | c.1392_1409del p.P465_G470del | In Frame Del (DEL) | VAF 13/61 reads (21%) | called by mutect2, pindel, varscan2
- CCSER1 | c.2626T>A p.Y876N | Missense Mutation (SNP) | VAF 46/163 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CD164L2 | c.220A>T p.S74C | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.428); called by muse, mutect2, varscan2
- CD99L2 | c.667G>T p.A223S | Missense Mutation (SNP) | VAF 20/226 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.285); called by muse, mutect2
- CDH23 | c.546C>A p.S182R | Missense Mutation (SNP) | VAF 58/205 reads (28%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.768); called by muse, mutect2, varscan2
- CDH6 | c.241C>A p.Q81K | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT tolerated (0.72); PolyPhen benign (0.035); called by mutect2, varscan2
- CDK14 | c.1078G>C p.V360L (on ENST00000380050 / NM_001287135.2; = p.V342L on NM_012395.3) | Missense Mutation (SNP) | VAF 31/243 reads (13%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.8); called by muse, mutect2, varscan2
- CEP170 | c.2141G>T p.G714V | Missense Mutation (SNP) | VAF 78/631 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, varscan2
- CFAP46 | c.8110C>T p.Q2704* | Nonsense Mutation (SNP) | VAF 16/65 reads (25%) | called by muse, mutect2, varscan2
- CHORDC1 | c.654G>T p.W218C | Missense Mutation (SNP) | VAF 70/357 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CHRM3 | c.1153T>A p.S385T | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- CHST8 | c.1053G>T p.M351I | Missense Mutation (SNP) | VAF 43/265 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.262); called by muse, mutect2, varscan2
- CITED2 | c.298G>T p.G100C | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- CLDN34 | c.350G>C p.R117T | Missense Mutation (SNP) | VAF 23/155 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- COL11A1 | c.2953G>T p.G985W | Missense Mutation (SNP) | VAF 104/420 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL4A5 | c.1937C>T p.P646L | Missense Mutation (SNP) | VAF 56/195 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- COL4A6 | c.3085C>G p.P1029A | Missense Mutation (SNP) | VAF 67/224 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CPB2 | c.789C>A p.H263Q | Missense Mutation (SNP) | VAF 36/232 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.437); called by muse, mutect2, varscan2
- CPT1C | c.1659G>T p.K553N | Missense Mutation (SNP) | VAF 66/290 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CUL9 | c.2824C>T p.Q942* | Nonsense Mutation (SNP) | VAF 14/104 reads (13%) | called by muse, mutect2, varscan2
- CYP11B1 | c.393G>T p.L131F | Missense Mutation (SNP) | VAF 54/754 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); called by muse, mutect2
- DBX1 | c.247G>T p.G83C | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- DCC | c.1600C>A p.L534M | Missense Mutation (SNP) | VAF 28/472 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2
- DCST1 | c.1336C>T p.P446S | Missense Mutation (SNP) | VAF 22/352 reads (6%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.517); called by muse, mutect2
- DHX30 | c.2189C>T p.A730V (on ENST00000445061 / NM_138615.3; = p.A691V on NM_014966.3) | Missense Mutation (SNP) | VAF 30/236 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- DPPA4 | c.523G>T p.E175* | Nonsense Mutation (SNP) | VAF 122/517 reads (24%) | called by muse, mutect2, varscan2
- DRP2 | c.2584C>A p.Q862K | Missense Mutation (SNP) | VAF 15/140 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- DSC2 | c.1022G>T p.C341F | Missense Mutation (SNP) | VAF 57/426 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- EIF3B | c.2105T>C p.L702P | Missense Mutation (SNP) | VAF 25/287 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- EPHA3 | c.1540G>T p.A514S | Missense Mutation (SNP) | VAF 38/262 reads (15%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ERICH3 | c.2286G>T p.L762F | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- FAM160A1 | c.2445A>G p.I815M | Missense Mutation (SNP) | VAF 53/185 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FANCM | c.2005A>T p.M669L | Missense Mutation (SNP) | VAF 28/168 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAT3 | c.5494del p.A1832Qfs*22 | Frame Shift Del (DEL) | VAF 21/167 reads (13%) | called by mutect2, pindel, varscan2
- FAT4 | c.3883del p.L1295Sfs*7 | Frame Shift Del (DEL) | VAF 64/256 reads (25%) | called by mutect2, pindel, varscan2
- FCGBP | c.951G>T p.L317F | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- FDCSP | c.31A>T p.I11F | Missense Mutation (SNP) | VAF 54/212 reads (25%) | SIFT tolerated, low confidence (0.2); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- FER1L5 | c.6180T>A p.D2060E (on ENST00000623019; = p.D2024E on NM_001293083.2) | Missense Mutation (SNP) | VAF 118/427 reads (28%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FER1L6 | c.911G>C p.W304S | Missense Mutation (SNP) | VAF 140/243 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FIG4 | c.186A>T p.E62D | Missense Mutation (SNP) | VAF 103/482 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- FLNC | c.379C>A p.L127M | Missense Mutation (SNP) | VAF 78/422 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FREM1 | c.6087G>T p.K2029N | Missense Mutation (SNP) | VAF 31/294 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- FRG2C | c.748C>A p.P250T | Missense Mutation (SNP) | VAF 124/612 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- FRY | c.7663C>T p.L2555F | Missense Mutation (SNP) | VAF 57/324 reads (18%) | SIFT tolerated (0.51); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FTO | c.810G>T p.W270C | Missense Mutation (SNP) | VAF 54/476 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FZD6 | c.1202A>T p.Q401L | Missense Mutation (SNP) | VAF 258/836 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- GAD2 | c.1153G>T p.E385* | Nonsense Mutation (SNP) | VAF 24/179 reads (13%) | called by muse, mutect2, varscan2
- GAPDHS | c.687G>C p.L229F | Missense Mutation (SNP) | VAF 52/313 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- GHRHR | c.409C>A p.H137N | Missense Mutation (SNP) | VAF 132/863 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- GLDC | c.83C>T p.P28L | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT tolerated, low confidence (0.9); PolyPhen benign (0); called by muse, mutect2, varscan2
- GLI3 | c.523A>T p.R175W | Missense Mutation (SNP) | VAF 92/522 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GLI4 | c.843C>A p.N281K | Missense Mutation (SNP) | VAF 14/250 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.83); called by muse, mutect2
- GPI | c.795G>T p.E265D | Missense Mutation (SNP) | VAF 116/470 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.369); called by muse, mutect2, varscan2
- GPR161 | c.883C>A p.L295I | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- GPR33 | c.634C>A p.L212M | Missense Mutation (SNP) | VAF 71/219 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- GPRASP1 | c.754G>C p.G252R | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- GRB7 | c.1598G>T p.*533Lext*34 | Nonstop Mutation (SNP) | VAF 8/46 reads (17%) | called by muse, mutect2, varscan2
- GRM5 | c.2054C>A p.P685H | Missense Mutation (SNP) | VAF 67/325 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GRM5 | c.854G>T p.G285V | Missense Mutation (SNP) | VAF 78/464 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- GRM8 | c.1977G>T p.M659I | Missense Mutation (SNP) | VAF 66/245 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- H1-4 | c.565G>C p.A189P | Missense Mutation (SNP) | VAF 64/255 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- H2BC6 | c.364T>A p.Y122N | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- HAS1 | c.1511T>A p.L504Q | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- HCN1 | c.1021T>C p.W341R | Missense Mutation (SNP) | VAF 23/724 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.593); called by muse, mutect2
- HECTD4 | c.9197C>T p.S3066F | Missense Mutation (SNP) | VAF 58/154 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HMGCLL1 | c.801G>C p.M267I | Missense Mutation (SNP) | VAF 40/275 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- HSD17B3 | c.442G>T p.D148Y | Missense Mutation (SNP) | VAF 79/325 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- HYDIN | c.13534C>A p.L4512M | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ICE1 | c.4724G>T p.R1575I | Missense Mutation (SNP) | VAF 18/153 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- IFIH1 | c.1943G>T p.G648V | Missense Mutation (SNP) | VAF 69/308 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- IFT172 | c.815G>T p.R272I | Missense Mutation (SNP) | VAF 25/144 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- IFTAP | c.467G>T p.S156I | Missense Mutation (SNP) | VAF 37/198 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IMPG2 | c.3489dup p.E1164* | Frame Shift Ins (INS) | VAF 38/349 reads (11%) | called by mutect2, pindel, varscan2
- INO80 | c.2959G>T p.V987F | Missense Mutation (SNP) | VAF 26/250 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- IQSEC2 | c.944G>C p.R315P (on ENST00000642864 / NM_001111125.3; = p.R110P on NM_015075.2) | Missense Mutation (SNP) | VAF 44/264 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IRX2 | c.73G>T p.A25S | Missense Mutation (SNP) | VAF 12/218 reads (6%) | SIFT tolerated (0.5); PolyPhen benign (0.081); called by muse, mutect2
- ITGA3 | c.2077G>A p.A693T | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT tolerated (0.54); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ITGA6 | c.156G>T p.W52C | Missense Mutation (SNP) | VAF 48/160 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- ITGAM | c.408G>T p.K136N | Missense Mutation (SNP) | VAF 58/231 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KCNA4 | c.307C>A p.P103T | Missense Mutation (SNP) | VAF 58/313 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- KCND3 | c.1450del p.E484Kfs*112 | Frame Shift Del (DEL) | VAF 137/697 reads (20%) | called by mutect2, pindel, varscan2
- KCNK6 | c.800A>T p.E267V | Missense Mutation (SNP) | VAF 70/289 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- KCNT2 | c.2631G>T p.M877I | Missense Mutation (SNP) | VAF 102/488 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- KEL | c.1819G>T p.A607S | Missense Mutation (SNP) | VAF 153/561 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0.241); called by mutect2, varscan2
- KIAA1217 | c.1235G>T p.G412V | Missense Mutation (SNP) | VAF 36/215 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KLHL14 | c.1397G>A p.G466E | Missense Mutation (SNP) | VAF 9/144 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KLHL30 | c.1711C>T p.P571S | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.261); called by muse, mutect2
- KRTAP10-6 | c.899C>A p.S300Y | Missense Mutation (SNP) | VAF 44/305 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KRTAP24-1 | c.646A>G p.T216A | Missense Mutation (SNP) | VAF 96/558 reads (17%) | SIFT tolerated (0.47); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KXD1 | c.488A>T p.N163I | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- LANCL3 | c.335C>T p.P112L | Missense Mutation (SNP) | VAF 4/55 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0.015); called by muse, mutect2
- LCOR | c.4320G>T p.R1440S | Missense Mutation (SNP) | VAF 41/137 reads (30%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- LGR6 | c.109del p.A37Pfs*31 | Frame Shift Del (DEL) | VAF 10/93 reads (11%) | called by mutect2, pindel, varscan2
- LILRA1 | c.1423C>A p.L475I | Missense Mutation (SNP) | VAF 84/323 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.496); called by muse, mutect2, varscan2
- LIPF | c.193C>A p.P65T | Missense Mutation (SNP) | VAF 21/134 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LMNTD1 | c.78G>T p.M26I | Missense Mutation (SNP) | VAF 80/342 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRP8 | c.668C>T p.P223L | Missense Mutation (SNP) | VAF 28/215 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.44); called by muse, mutect2, varscan2
- LRRC10B | c.227T>C p.F76S | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, mutect2
- LRRC4C | c.613G>T p.A205S | Missense Mutation (SNP) | VAF 40/328 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- LTB | c.460G>T p.G154C | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- LYPD2 | c.193G>T p.G65W | Missense Mutation (SNP) | VAF 19/302 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.228); called by muse, mutect2
- MAGEA1 | c.798G>T p.W266C | Missense Mutation (SNP) | VAF 26/264 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAGEB2 | c.223G>T p.G75C | Missense Mutation (SNP) | VAF 23/162 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- MAGEB6B | c.1132G>C p.E378Q | Missense Mutation (SNP) | VAF 44/282 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- MAP3K7 | c.131G>A p.R44K | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT tolerated (0.81); PolyPhen benign (0.023); called by muse, varscan2
- MASP1 | c.1470C>A p.H490Q | Missense Mutation (SNP) | VAF 89/495 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MBNL1 | c.505G>T p.A169S | Missense Mutation (SNP) | VAF 61/308 reads (20%) | SIFT tolerated (0.51); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- MDGA2 | c.1862G>T p.G621V (on ENST00000399232 / NM_001113498.2; = p.G323V on NM_182830.4) | Missense Mutation (SNP) | VAF 12/247 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.462); called by muse, mutect2
- MIPEP | c.442A>T p.M148L | Missense Mutation (SNP) | VAF 27/234 reads (12%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- MMEL1 | c.501G>T p.K167N | Missense Mutation (SNP) | VAF 41/205 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MMUT | c.2030G>C p.G677A | Missense Mutation (SNP) | VAF 65/355 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- MPC2 | c.229G>T p.A77S | Missense Mutation (SNP) | VAF 58/289 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.362); called by muse, mutect2, varscan2
- MROH2B | c.4451G>C p.R1484T | Missense Mutation (SNP) | VAF 25/271 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.415); called by muse, mutect2
- MS4A1 | c.448G>C p.E150Q | Missense Mutation (SNP) | VAF 49/359 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.739); called by muse, mutect2, varscan2
- MTMR4 | c.632G>T p.R211L | Missense Mutation (SNP) | VAF 64/205 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MUC16 | c.33238G>T p.E11080* | Nonsense Mutation (SNP) | VAF 33/121 reads (27%) | called by muse, mutect2, varscan2
- MUC16 | c.22750A>T p.R7584* | Nonsense Mutation (SNP) | VAF 55/184 reads (30%) | called by muse, mutect2, varscan2
- MUC16 | c.17038C>A p.P5680T | Missense Mutation (SNP) | VAF 107/374 reads (29%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MXRA5 | c.4291C>A p.P1431T | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT tolerated (0.42); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- MYB | c.703A>C p.T235P | Missense Mutation (SNP) | VAF 100/411 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYCN | c.254A>G p.N85S | Missense Mutation (SNP) | VAF 40/254 reads (16%) | SIFT tolerated (0.64); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- MYO5A | c.4495G>C p.G1499R | Missense Mutation (SNP) | VAF 21/356 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.769); called by muse, mutect2
- MYRFL | c.2147G>C p.R716P | Missense Mutation (SNP) | VAF 24/207 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NEDD4 | c.1937A>T p.N646I (on ENST00000508342 / NM_001284338.1; = p.N227I on NM_006154.4) | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.053); called by muse, mutect2
- NME7 | c.755G>T p.G252V | Missense Mutation (SNP) | VAF 40/228 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- NME7 | c.755-1G>T p.X252_splice | Splice Site (SNP) | VAF 40/226 reads (18%) | called by muse, mutect2, varscan2
- NR5A2 | c.95C>A p.P32H | Missense Mutation (SNP) | VAF 49/292 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.112); called by mutect2, varscan2
- NRXN2 | c.2339C>A p.T780N | Missense Mutation (SNP) | VAF 81/316 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- NRXN3 | c.426C>G p.H142Q (on ENST00000557594 / NM_001272020.2; = p.H774Q on NM_004796.6) | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.975); called by muse, mutect2
- NWD1 | c.2338G>T p.D780Y | Missense Mutation (SNP) | VAF 59/364 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- OR10J3 | c.141G>T p.M47I | Missense Mutation (SNP) | VAF 41/405 reads (10%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2
- OR11H2 | c.796C>A p.P266T (on ENST00000556246; = p.P277T on NM_001197287.1) | Missense Mutation (SNP) | VAF 85/566 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by mutect2, varscan2
- OR2AP1 | c.602C>A p.A201E | Missense Mutation (SNP) | VAF 51/138 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR2J1 | c.551C>G p.A184G | Missense Mutation (SNP) | VAF 42/343 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- OR52N1 | c.710A>G p.Q237R | Missense Mutation (SNP) | VAF 64/386 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- OTOG | c.7024C>A p.Q2342K | Missense Mutation (SNP) | VAF 14/216 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.765); called by muse, mutect2
- OTOL1 | c.490G>T p.G164* | Nonsense Mutation (SNP) | VAF 60/286 reads (21%) | called by muse, mutect2, varscan2
- OTUD5 | c.881G>T p.R294L | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- OVCH2 | c.538G>A p.G180S | Missense Mutation (SNP) | VAF 29/240 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- P3H3 | c.1231G>T p.A411S | Missense Mutation (SNP) | VAF 99/346 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- PAK5 | c.757A>T p.S253C | Missense Mutation (SNP) | VAF 37/254 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- PCDH11X | c.263G>T p.G88V | Missense Mutation (SNP) | VAF 81/529 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- PCDH11X | c.2900C>G p.P967R | Missense Mutation (SNP) | VAF 75/555 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDH15 | c.5467C>A p.P1823T | Missense Mutation (SNP) | VAF 68/226 reads (30%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- PCNT | c.5995-1G>T p.X1999_splice | Splice Site (SNP) | VAF 94/469 reads (20%) | called by muse, mutect2, varscan2
- PDGFA | c.388A>C p.T130P | Missense Mutation (SNP) | VAF 50/269 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- PHF3 | c.2635G>T p.E879* | Nonsense Mutation (SNP) | VAF 18/82 reads (22%) | called by muse, mutect2, varscan2
- PIEZO2 | c.2289G>A p.W763* | Nonsense Mutation (SNP) | VAF 19/303 reads (6%) | called by muse, mutect2
- PIWIL3 | c.1183A>C p.I395L | Missense Mutation (SNP) | VAF 62/376 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- PKHD1L1 | c.3881G>T p.C1294F | Missense Mutation (SNP) | VAF 38/553 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); called by muse, mutect2
- PLCB4 | c.1622C>A p.T541N | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by mutect2, varscan2
- PLD3 | c.643G>T p.G215C | Missense Mutation (SNP) | VAF 47/159 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLEKHF1 | c.604C>T p.R202C | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLEKHM2 | c.922A>G p.T308A | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- PLXNA1 | c.4194G>C p.Q1398H | Missense Mutation (SNP) | VAF 16/270 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.964); called by muse, mutect2
- POTEF | c.1552A>G p.K518E | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); called by mutect2, varscan2
- POTEH | c.120G>T p.K40N | Missense Mutation (SNP) | VAF 99/894 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); called by muse, varscan2
- PPP4R2 | c.739dup p.R247Kfs*5 | Frame Shift Ins (INS) | VAF 44/328 reads (13%) | called by mutect2, pindel, varscan2
- PRAME | c.849G>T p.Q283H | Missense Mutation (SNP) | VAF 38/195 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PRAMEF7 | c.1303G>T p.E435* | Nonsense Mutation (SNP) | VAF 78/956 reads (8%) | called by muse, mutect2
- PRDM10 | c.850A>G p.M284V | Missense Mutation (SNP) | VAF 99/434 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- PRG3 | c.506G>T p.W169L | Missense Mutation (SNP) | VAF 22/129 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.031); called by muse, mutect2
- PRKCA | c.1438G>T p.A480S | Missense Mutation (SNP) | VAF 12/306 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); called by muse, mutect2
- PRKCB | c.529+1G>T p.X177_splice | Splice Site (SNP) | VAF 18/118 reads (15%) | called by muse, mutect2, varscan2
- PRKX | c.919G>A p.D307N | Missense Mutation (SNP) | VAF 43/293 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- PRMT2 | c.958G>T p.E320* | Nonsense Mutation (SNP) | VAF 28/131 reads (21%) | called by muse, mutect2, varscan2
- PRR23A | c.14C>A p.P5H | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.304); called by muse, mutect2, varscan2
- PRSS41 | c.940C>A p.H314N | Missense Mutation (SNP) | VAF 38/241 reads (16%) | SIFT tolerated (0.69); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PSMB9 | c.357G>T p.M119I | Missense Mutation (SNP) | VAF 37/182 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTCH1 | c.1858A>G p.S620G | Missense Mutation (SNP) | VAF 81/340 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- PTK7 | c.1007G>A p.G336D | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.79); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- PTPN18 | c.757-1G>T p.X253_splice | Splice Site (SNP) | VAF 78/232 reads (34%) | called by muse, mutect2, varscan2
- PYGL | c.2370G>T p.Q790H | Missense Mutation (SNP) | VAF 69/536 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- QSOX2 | c.617G>T p.R206L | Missense Mutation (SNP) | VAF 46/191 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- RAB37 | c.566+5G>T | Splice Region (SNP) | VAF 131/294 reads (45%) | called by muse, mutect2, varscan2
- RASGRP2 | c.1742G>T p.R581L | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- RB1CC1 | c.568A>T p.T190S | Missense Mutation (SNP) | VAF 20/284 reads (7%) | SIFT tolerated (0.39); PolyPhen benign (0.14); called by muse, mutect2
- RBBP6 | c.4816C>A p.Q1606K | Missense Mutation (SNP) | VAF 20/277 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2
- RBM25 | c.14C>T p.P5L | Missense Mutation (SNP) | VAF 56/337 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- RBM6 | c.2541G>T p.M847I | Missense Mutation (SNP) | VAF 39/202 reads (19%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- REG1B | c.226C>G p.L76V | Missense Mutation (SNP) | VAF 49/272 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- RFFL | c.533C>T p.P178L | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.021); called by muse, mutect2
- RGPD3 | c.2893C>A p.Q965K | Missense Mutation (SNP) | VAF 170/1109 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.057); called by muse, varscan2
- RRP12 | c.1418+1G>A p.X473_splice | Splice Site (SNP) | VAF 7/58 reads (12%) | called by muse, mutect2, varscan2
- RSL1D1 | c.1126C>A p.P376T | Missense Mutation (SNP) | VAF 25/173 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- RUNX3 | c.58G>T p.D20Y | Missense Mutation (SNP) | VAF 51/248 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); called by muse, mutect2
- SAG | c.182-1G>T p.X61_splice | Splice Site (SNP) | VAF 17/70 reads (24%) | called by muse, mutect2, varscan2
- SCN11A | c.2299G>T p.G767W | Missense Mutation (SNP) | VAF 45/182 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SDK2 | c.4298G>T p.R1433L | Missense Mutation (SNP) | VAF 61/209 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SERPINA7 | c.896+1G>T p.X299_splice | Splice Site (SNP) | VAF 79/409 reads (19%) | called by muse, mutect2, varscan2
- SETX | c.6777G>C p.R2259S | Missense Mutation (SNP) | VAF 24/523 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SGCG | c.332T>A p.V111E | Missense Mutation (SNP) | VAF 80/470 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- SH3GL2 | c.491G>C p.R164P | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SI | c.4820T>G p.V1607G | Missense Mutation (SNP) | VAF 21/400 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SKI | c.64G>T p.E22* | Nonsense Mutation (SNP) | VAF 52/218 reads (24%) | called by muse, mutect2, varscan2
- SLC4A10 | c.1663T>C p.Y555H (on ENST00000446997 / NM_001354461.2; = p.Y525H on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 61/277 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- SLCO1B1 | c.395C>G p.S132* | Nonsense Mutation (SNP) | VAF 66/216 reads (31%) | called by muse, mutect2, varscan2
- SNX27 | c.985+8C>A | Splice Region (SNP) | VAF 26/70 reads (37%) | called by muse, mutect2, varscan2
- SORCS1 | c.2062del p.E688Kfs*94 | Frame Shift Del (DEL) | VAF 32/132 reads (24%) | called by mutect2, pindel
- SORCS3 | c.2187G>T p.Q729H | Missense Mutation (SNP) | VAF 72/292 reads (25%) | SIFT tolerated (0.46); PolyPhen benign (0.321); called by muse, varscan2
- SOWAHB | c.355C>T p.Q119* | Nonsense Mutation (SNP) | VAF 9/144 reads (6%) | called by muse, mutect2
- SOX3 | c.390dup p.G131Wfs*38 | Frame Shift Ins (INS) | VAF 8/60 reads (13%) | called by mutect2, pindel, varscan2
- SP140 | c.847C>T p.Q283* | Nonsense Mutation (SNP) | VAF 64/189 reads (34%) | called by muse, mutect2, varscan2
- SPECC1 | c.2225C>G p.A742G | Missense Mutation (SNP) | VAF 105/324 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- SPEN | c.2687T>C p.V896A | Missense Mutation (SNP) | VAF 38/217 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SPESP1 | c.53C>G p.P18R | Missense Mutation (SNP) | VAF 18/312 reads (6%) | SIFT tolerated (0.7); PolyPhen benign (0.431); called by muse, mutect2
- SPTA1 | c.3164A>T p.Q1055L | Missense Mutation (SNP) | VAF 84/430 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0); called by mutect2, varscan2
- STON2 | c.1993C>T p.L665F (on ENST00000649389 / NM_001366849.2; = p.L608F on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/146 reads (23%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- STYXL2 | c.1367A>T p.E456V | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- SUPV3L1 | c.2012A>G p.H671R | Missense Mutation (SNP) | VAF 83/245 reads (34%) | SIFT tolerated (0.37); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SYT6 | c.829C>A p.R277S (on ENST00000610222 / NM_001366225.1; = p.R192S on NM_205848.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/190 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- SYTL5 | c.229del p.R77Gfs*10 | Frame Shift Del (DEL) | VAF 40/373 reads (11%) | called by mutect2, pindel, varscan2
- TAAR8 | c.915G>T p.M305I | Missense Mutation (SNP) | VAF 28/171 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TACR3 | c.1076T>C p.L359P | Missense Mutation (SNP) | VAF 63/377 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TADA2A | c.605-1G>T p.X202_splice | Splice Site (SNP) | VAF 29/114 reads (25%) | called by muse, mutect2, varscan2
- TBCD | c.2285C>T p.A762V | Missense Mutation (SNP) | VAF 18/158 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TCAF2 | c.2275C>A p.L759M | Missense Mutation (SNP) | VAF 41/292 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TENM2 | c.641C>G p.P214R | Missense Mutation (SNP) | VAF 87/351 reads (25%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TENM4 | c.4016G>T p.G1339V | Missense Mutation (SNP) | VAF 48/175 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- TEX13C | c.2846A>T p.K949M | Missense Mutation (SNP) | VAF 36/481 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- TEX14 | c.3011G>T p.G1004V (on ENST00000240361 / NM_001201457.2; = p.G998V on NM_031272.5) | Missense Mutation (SNP) | VAF 18/310 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2
- TEX55 | c.1524C>A p.H508Q | Missense Mutation (SNP) | VAF 49/381 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.74); called by muse, mutect2, varscan2
- TLN2 | c.7608G>T p.E2536D | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- TMLHE | c.416A>T p.E139V | Missense Mutation (SNP) | VAF 34/191 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- TOPAZ1 | c.2975T>A p.V992E | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.714); called by muse, mutect2
- TRABD2B | c.734C>A p.S245Y | Missense Mutation (SNP) | VAF 42/260 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.484); called by muse, mutect2, varscan2
- TRAF5 | c.35G>T p.C12F | Missense Mutation (SNP) | VAF 63/243 reads (26%) | SIFT tolerated (0.63); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TRPM2 | c.2299C>A p.L767I | Missense Mutation (SNP) | VAF 29/160 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- TRPM6 | c.4523A>T p.Q1508L | Missense Mutation (SNP) | VAF 134/498 reads (27%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- TRPM6 | c.4009G>C p.A1337P | Missense Mutation (SNP) | VAF 140/511 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- TSKU | c.470G>T p.G157V | Missense Mutation (SNP) | VAF 29/174 reads (17%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- TUBB6 | c.446C>A p.T149K | Missense Mutation (SNP) | VAF 66/164 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- UGGT2 | c.487A>C p.T163P | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- UMOD | c.745G>A p.A249T | Missense Mutation (SNP) | VAF 43/212 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- UNC13A | c.2726C>G p.A909G | Missense Mutation (SNP) | VAF 35/177 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); called by muse, mutect2, varscan2
- UTP14A | c.1680C>A p.D560E | Missense Mutation (SNP) | VAF 21/182 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- VGLL3 | c.828G>T p.Q276H | Missense Mutation (SNP) | VAF 85/397 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- VPS13C | c.10367C>T p.A3456V (on ENST00000644861 / NM_020821.3; = p.A3413V on NM_017684.5) | Missense Mutation (SNP) | VAF 14/249 reads (6%) | SIFT tolerated (0.83); PolyPhen benign (0.443); called by muse, mutect2
- VWF | c.6253T>A p.C2085S | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- WDFY3 | c.8590G>T p.D2864Y | Missense Mutation (SNP) | VAF 7/97 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- WDR17 | c.176T>G p.L59R | Missense Mutation (SNP) | VAF 33/154 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- WDR24 | c.263A>T p.D88V (on ENST00000248142; = p.D26V on NM_032259.4) | Missense Mutation (SNP) | VAF 20/228 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); called by muse, mutect2
- WSCD2 | c.88G>T p.G30W | Missense Mutation (SNP) | VAF 63/185 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- XKR6 | c.1058G>T p.S353I | Missense Mutation (SNP) | VAF 23/154 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- XPNPEP2 | c.1945G>C p.A649P | Missense Mutation (SNP) | VAF 18/144 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZAN | c.4500C>A p.C1500* | Nonsense Mutation (SNP) | VAF 26/121 reads (21%) | called by muse, mutect2, varscan2
- ZBTB8B | c.433G>T p.A145S | Missense Mutation (SNP) | VAF 28/137 reads (20%) | SIFT tolerated (0.86); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ZDHHC6 | c.267+1G>A p.X89_splice | Splice Site (SNP) | VAF 5/35 reads (14%) | called by muse, mutect2, varscan2
- ZEB1 | c.100G>T p.D34Y | Missense Mutation (SNP) | VAF 94/388 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZFAND5 | c.5C>A p.A2D | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); called by muse, mutect2, varscan2
- ZFHX4 | c.7537C>T p.H2513Y | Missense Mutation (SNP) | VAF 48/620 reads (8%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.931); called by muse, mutect2
- ZNF133 | c.1832G>T p.C611F (on ENST00000316358 / NM_001352454.2; = p.C610F on NM_003434.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/186 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); called by muse, mutect2, varscan2
- ZNF14 | c.1691G>T p.C564F | Missense Mutation (SNP) | VAF 53/184 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF280A | c.953A>T p.H318L | Missense Mutation (SNP) | VAF 59/374 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); called by muse, mutect2, varscan2
- ZNF280B | c.1196G>T p.G399V | Missense Mutation (SNP) | VAF 92/410 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- ZNF366 | c.1897C>A p.P633T | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- ZNF521 | c.3344G>T p.R1115I | Missense Mutation (SNP) | VAF 24/140 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- ZNF555 | c.1165A>T p.T389S | Missense Mutation (SNP) | VAF 61/282 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- ZNF668 | c.199G>T p.E67* | Nonsense Mutation (SNP) | VAF 33/237 reads (14%) | called by muse, mutect2, varscan2
- ZNF729 | c.2152G>A p.G718S | Missense Mutation (SNP) | VAF 111/388 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF860 | c.1714G>A p.D572N | Missense Mutation (SNP) | VAF 50/270 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- ZNRF4 | c.110C>T p.P37L | Missense Mutation (SNP) | VAF 27/153 reads (18%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- ZRSR2 | c.18G>T p.K6N | Missense Mutation (SNP) | VAF 18/147 reads (12%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABCA4 | c.5721C>T p.A1907= | Silent (SNP) | VAF 24/366 reads (7%) | catalogued as rs368502305; called by muse, mutect2
- ABCB11 | c.2217C>A p.A739= | Silent (SNP) | VAF 39/175 reads (22%) | called by muse, mutect2, varscan2
- ACTN3 | c.1821C>A p.I607= | Silent (SNP) | VAF 16/80 reads (20%) | called by muse, mutect2, varscan2
- ADNP | c.3033A>T p.P1011= | Silent (SNP) | VAF 19/355 reads (5%) | catalogued as COSV62426297; called by muse, mutect2
- ANO3 | c.2481T>C p.N827= | Silent (SNP) | VAF 22/117 reads (19%) | called by muse, mutect2, varscan2
- ANXA8 | c.216T>A p.T72= | Silent (SNP) | VAF 69/360 reads (19%) | called by muse, mutect2, varscan2
- APEX2 | c.1473C>A p.R491= | Silent (SNP) | VAF 9/84 reads (11%) | called by muse, mutect2, varscan2
- ARHGAP6 | c.250C>A p.R84= | Silent (SNP) | VAF 12/69 reads (17%) | called by muse, mutect2, varscan2
- ASXL3 | c.2154G>T p.P718= | Silent (SNP) | VAF 38/222 reads (17%) | catalogued as rs370185733, COSV52471685; called by muse, mutect2, varscan2
- ATP2B2 | c.1617C>A p.T539= (on ENST00000352432; = p.T505= on NM_001683.5) | Silent (SNP) | VAF 96/441 reads (22%) | catalogued as COSV59498991; called by muse, mutect2, varscan2
- ATP2B2 | c.495C>A p.V165= | Silent (SNP) | VAF 133/544 reads (24%) | called by muse, mutect2, varscan2
- ATP4A | c.633C>A p.P211= | Silent (SNP) | VAF 88/300 reads (29%) | called by muse, mutect2, varscan2
- BAIAP3 | c.2091G>A p.L697= | Silent (SNP) | VAF 31/179 reads (17%) | catalogued as rs1179459089; called by muse, mutect2, varscan2
- C1QTNF8 | c.309G>A p.G103= | Silent (SNP) | VAF 10/50 reads (20%) | called by muse, mutect2, varscan2
- C2orf16 | c.591G>T p.R197= | Silent (SNP) | VAF 25/138 reads (18%) | called by muse, mutect2, varscan2
- CBLN2 | c.198G>A p.V66= | Silent (SNP) | VAF 17/148 reads (11%) | called by muse, mutect2, varscan2
- CDC45 | c.1476G>A p.V492= | Silent (SNP) | VAF 85/319 reads (27%) | catalogued as rs368177257; called by muse, varscan2
- CNNM3 | c.855G>T p.R285= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as rs1381405980; called by muse, mutect2, varscan2
- COL4A6 | c.43C>T p.L15= | Silent (SNP) | VAF 71/293 reads (24%) | called by muse, mutect2, varscan2
- CSMD3 | c.5460G>T p.G1820= (on ENST00000297405 / NM_001363185.1; = p.G1716= on NM_052900.3) | Silent (SNP) | VAF 374/811 reads (46%) | catalogued as COSV52168987; called by muse, varscan2
- DGKD | c.993G>A p.G331= (on ENST00000264057 / NM_152879.3; = p.G287= on NM_003648.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 28/108 reads (26%) | catalogued as rs1559548597; called by muse, mutect2, varscan2
- DNAH3 | c.9423C>A p.I3141= | Silent (SNP) | VAF 44/236 reads (19%) | called by muse, mutect2, varscan2
- DSPP | c.126G>A p.V42= | Silent (SNP) | VAF 49/551 reads (9%) | called by muse, mutect2
- EGFLAM | c.1530C>G p.L510= | Silent (SNP) | VAF 55/230 reads (24%) | called by muse, varscan2
- ELOA2 | c.1347C>T p.A449= | Silent (SNP) | VAF 42/460 reads (9%) | called by muse, mutect2
- EPPK1 | c.4131G>T p.A1377= | Silent (SNP) | VAF 10/167 reads (6%) | called by muse, mutect2
- FBXL7 | c.669C>T p.Y223= | Silent (SNP) | VAF 106/274 reads (39%) | catalogued as rs1474634874; called by muse, mutect2, varscan2
- FGF5 | c.573C>A p.A191= | Silent (SNP) | VAF 76/250 reads (30%) | catalogued as COSV100428114; called by muse, mutect2, varscan2
- FLT1 | c.351G>A p.K117= | Silent (SNP) | VAF 28/283 reads (10%) | called by muse, mutect2
- FRYL | c.1065A>C p.A355= | Silent (SNP) | VAF 25/200 reads (13%) | called by muse, mutect2, varscan2
- GABRR2 | c.1185C>T p.S395= | Silent (SNP) | VAF 33/285 reads (12%) | called by muse, mutect2, varscan2
- GJA8 | c.900C>T p.F300= | Silent (SNP) | VAF 15/221 reads (7%) | catalogued as rs782293999, COSV53789063; called by muse, mutect2
- GLIS1 | c.1293G>T p.L431= | Silent (SNP) | VAF 33/147 reads (22%) | catalogued as COSV56556256; called by muse, mutect2, varscan2
- GPR31 | c.939C>T p.N313= | Silent (SNP) | VAF 6/28 reads (21%) | called by muse, varscan2
- GTF3C2 | c.2091G>A p.K697= | Silent (SNP) | VAF 84/401 reads (21%) | called by muse, mutect2, varscan2
- H3-3B | c.390G>T p.R130= | Silent (SNP) | VAF 10/136 reads (7%) | called by muse, mutect2
- HAP1 | c.1161G>A p.L387= | Silent (SNP) | VAF 34/305 reads (11%) | catalogued as rs1170473985; called by muse, mutect2, varscan2
- HDAC6 | c.345C>A p.I115= | Silent (SNP) | VAF 23/231 reads (10%) | called by muse, mutect2, varscan2
- HEATR1 | c.2124G>T p.L708= | Silent (SNP) | VAF 29/343 reads (8%) | called by muse, mutect2
- LRRC7 | c.2472C>A p.A824= (on ENST00000651989 / NM_001370785.2; = p.A791= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 37/146 reads (25%) | called by muse, mutect2, varscan2
- MED12 | c.5196C>A p.P1732= | Silent (SNP) | VAF 21/97 reads (22%) | called by muse, mutect2, varscan2
- MUC16 | c.35856A>C p.T11952= | Silent (SNP) | VAF 26/117 reads (22%) | called by muse, mutect2, varscan2
- MUC5B | c.6933C>T p.T2311= | Silent (SNP) | VAF 50/422 reads (12%) | called by muse, mutect2, varscan2
- MYH8 | c.5601G>T p.L1867= | Silent (SNP) | VAF 126/462 reads (27%) | called by mutect2, varscan2
- MYO16 | c.3198G>A p.G1066= | Silent (SNP) | VAF 36/315 reads (11%) | catalogued as rs1326074883; called by muse, mutect2, varscan2
- MYO16 | c.3960C>T p.S1320= | Silent (SNP) | VAF 23/169 reads (14%) | catalogued as rs147869634, COSV100696716; called by mutect2, varscan2
- MYT1L | c.2928C>T p.C976= | Silent (SNP) | VAF 71/262 reads (27%) | called by muse, mutect2, varscan2
- NFE2L3 | c.291G>T p.A97= | Silent (SNP) | VAF 71/188 reads (38%) | catalogued as rs993501236; called by muse, mutect2, varscan2
- NPAP1 | c.1986C>A p.P662= | Silent (SNP) | VAF 37/163 reads (23%) | called by muse, mutect2, varscan2
- NRDC | c.1416A>G p.P472= | Silent (SNP) | VAF 30/174 reads (17%) | catalogued as rs1248905388; called by muse, mutect2, varscan2
- NRDE2 | c.2644C>T p.L882= | Silent (SNP) | VAF 24/114 reads (21%) | called by muse, mutect2, varscan2
- NSUN5 | c.864G>T p.A288= | Silent (SNP) | VAF 27/126 reads (21%) | catalogued as rs368355769, COSV53094078, COSV99392381; called by muse, mutect2, varscan2
- OCA2 | c.1518C>A p.A506= | Silent (SNP) | VAF 26/480 reads (5%) | called by muse, mutect2
- OR11L1 | c.234G>T p.V78= | Silent (SNP) | VAF 73/285 reads (26%) | called by muse, mutect2, varscan2
- OR5B2 | c.237C>A p.V79= | Silent (SNP) | VAF 16/127 reads (13%) | catalogued as COSV56909737; called by muse, mutect2, varscan2
- OR5D14 | c.87C>A p.L29= | Silent (SNP) | VAF 31/150 reads (21%) | catalogued as rs1289880453; called by muse, mutect2, varscan2
- OR8H3 | c.618C>A p.T206= | Silent (SNP) | VAF 38/160 reads (24%) | called by muse, mutect2, varscan2
- PCDH15 | c.4695C>A p.G1565= | Silent (SNP) | VAF 87/327 reads (27%) | catalogued as COSV57321156; called by muse, mutect2, varscan2
- PCDH15 | c.1608A>T p.A536= | Silent (SNP) | VAF 33/457 reads (7%) | called by muse, mutect2
- PCSK1 | c.2133C>A p.S711= | Silent (SNP) | VAF 107/419 reads (26%) | called by muse, mutect2, varscan2
- PDE4B | c.1251G>T p.S417= | Silent (SNP) | VAF 41/162 reads (25%) | catalogued as COSV58470059; called by muse, mutect2, varscan2
- PHETA2 | c.183G>T p.R61= | Silent (SNP) | VAF 9/65 reads (14%) | called by muse, mutect2, varscan2
- PIGO | c.1392C>T p.I464= | Silent (SNP) | VAF 89/335 reads (27%) | catalogued as rs149790500; ClinVar: likely benign; called by muse, mutect2, varscan2
- PKHD1L1 | c.5334C>T p.D1778= | Silent (SNP) | VAF 162/315 reads (51%) | called by muse, mutect2, varscan2
- PPP1R16B | c.1476G>T p.L492= | Silent (SNP) | VAF 25/143 reads (17%) | called by muse, mutect2, varscan2
- RDH8 | c.985C>A p.R329= (on ENST00000651512; = p.R309= on NM_015725.4) | Silent (SNP) | VAF 15/81 reads (19%) | catalogued as COSV99408686; called by muse, mutect2, varscan2
- RGN | c.666A>T p.G222= | Silent (SNP) | VAF 29/187 reads (16%) | called by muse, mutect2, varscan2
- RHOXF2 | c.462A>G p.Q154= | Silent (SNP) | VAF 50/500 reads (10%) | catalogued as rs782058881; called by muse, mutect2
- RP1L1 | c.2307G>A p.R769= | Silent (SNP) | VAF 21/146 reads (14%) | called by muse, mutect2, varscan2
- S100G | c.123C>A p.P41= | Silent (SNP) | VAF 34/137 reads (25%) | called by muse, mutect2, varscan2
- SAMD3 | c.1512T>A p.P504= | Silent (SNP) | VAF 52/204 reads (25%) | catalogued as COSV62385528; called by muse, mutect2, varscan2
- SCN10A | c.2940C>A p.P980= | Silent (SNP) | VAF 23/86 reads (27%) | called by muse, mutect2, varscan2
- SCNN1B | c.534A>T p.S178= | Silent (SNP) | VAF 53/331 reads (16%) | called by muse, mutect2, varscan2
- SERPINA6 | c.637C>T p.L213= | Silent (SNP) | VAF 77/427 reads (18%) | catalogued as COSV100448453; called by muse, mutect2, varscan2
- SI | c.564G>T p.T188= | Silent (SNP) | VAF 36/284 reads (13%) | called by muse, varscan2
- SI | c.414A>T p.L138= | Silent (SNP) | VAF 132/584 reads (23%) | called by muse, mutect2, varscan2
- SLC13A2 | c.1014C>T p.I338= | Silent (SNP) | VAF 23/288 reads (8%) | called by muse, mutect2
- SLC27A6 | c.405C>T p.L135= | Silent (SNP) | VAF 11/35 reads (31%) | called by muse, mutect2, varscan2
- SLC9C2 | c.2406G>A p.L802= | Silent (SNP) | VAF 48/257 reads (19%) | called by muse, mutect2, varscan2
- SLIT2 | c.381G>A p.A127= | Silent (SNP) | VAF 43/337 reads (13%) | catalogued as rs1336735058, COSV56565505, COSV99879578; called by muse, mutect2, varscan2
- SVEP1 | c.7407C>G p.G2469= | Silent (SNP) | VAF 13/171 reads (8%) | called by muse, mutect2
- TAF2 | c.3492G>A p.K1164= | Silent (SNP) | VAF 471/918 reads (51%) | called by muse, mutect2, varscan2
- TAFA3 | c.36C>A p.G12= | Silent (SNP) | VAF 44/237 reads (19%) | catalogued as COSV62624848; called by muse, mutect2, varscan2
- TARS1 | c.786G>T p.R262= | Silent (SNP) | VAF 52/520 reads (10%) | called by muse, mutect2, varscan2
- TAS2R41 | c.126G>T p.L42= | Silent (SNP) | VAF 108/459 reads (24%) | called by muse, mutect2, varscan2
- TENM1 | c.1035G>T p.L345= | Silent (SNP) | VAF 56/210 reads (27%) | called by muse, mutect2, varscan2
- TEX13A | c.489C>A p.A163= | Silent (SNP) | VAF 12/113 reads (11%) | called by muse, mutect2
- THOC2 | c.3687A>G p.K1229= | Silent (SNP) | VAF 13/208 reads (6%) | called by muse, mutect2
- TMC8 | c.607C>T p.L203= | Silent (SNP) | VAF 36/505 reads (7%) | called by muse, mutect2
- TMPRSS13 | c.33A>T p.P11= | Silent (SNP) | VAF 50/196 reads (26%) | called by muse, mutect2, varscan2
- TRBV3-1 | c.27G>T p.V9= | Silent (SNP) | VAF 44/247 reads (18%) | called by muse, varscan2
- TRIM11 | c.816G>T p.V272= | Silent (SNP) | VAF 37/116 reads (32%) | catalogued as rs371952104; called by muse, mutect2, varscan2
- TRIM29 | c.66G>T p.P22= | Silent (SNP) | VAF 35/140 reads (25%) | catalogued as rs773439980, COSV100531420; called by muse, mutect2, varscan2
- TRIM33 | c.2751A>T p.T917= | Silent (SNP) | VAF 17/79 reads (22%) | called by muse, mutect2, varscan2
- TRIM58 | c.1137T>C p.N379= | Silent (SNP) | VAF 34/154 reads (22%) | called by muse, mutect2, varscan2
- TROAP | c.252G>T p.G84= | Silent (SNP) | VAF 62/195 reads (32%) | catalogued as rs764943094; called by muse, mutect2, varscan2
- TRPC4 | c.225C>A p.L75= | Silent (SNP) | VAF 17/125 reads (14%) | called by muse, varscan2
- TTN | c.94593C>A p.T31531= (on ENST00000591111; = p.T24107= on NM_003319.4) | Silent (SNP) | VAF 32/259 reads (12%) | called by muse, mutect2, varscan2
- UBQLNL | c.216G>T p.L72= | Silent (SNP) | VAF 24/170 reads (14%) | called by muse, mutect2, varscan2
- WDFY3 | c.8709G>T p.V2903= | Silent (SNP) | VAF 87/239 reads (36%) | catalogued as COSV55700713; called by muse, mutect2, varscan2
- ZNF280A | c.204A>T p.P68= | Silent (SNP) | VAF 46/165 reads (28%) | called by muse, mutect2, varscan2
- ZNF423 | c.2085C>A p.T695= (on ENST00000563137 / NM_001379286.1; = p.T687= on NM_015069.4) | Silent (SNP) | VAF 24/146 reads (16%) | called by muse, mutect2, varscan2
- ZNF469 | c.4416T>A p.S1472= (on ENST00000437464; = p.S1500= on NM_001367624.2) | Silent (SNP) | VAF 129/479 reads (27%) | called by muse, mutect2, varscan2
- ZNF521 | c.3759A>T p.G1253= | Silent (SNP) | VAF 19/319 reads (6%) | called by muse, mutect2
- AC007557.3 | n.2400G>T | RNA (SNP) | VAF 82/273 reads (30%) | called by muse, mutect2, varscan2
- AC011410.1 | n.120C>T | RNA (SNP) | VAF 22/241 reads (9%) | called by muse, mutect2
- AC090142.3 | chr8:104991665 G>A | 5'Flank (SNP) | VAF 49/606 reads (8%) | called by muse, mutect2
- AC136759.1 | n.1099A>G | RNA (SNP) | VAF 38/238 reads (16%) | catalogued as rs544450436; called by muse, varscan2
- ANKRD19P | n.30C>A | RNA (SNP) | VAF 20/472 reads (4%) | called by muse, mutect2
- ARHGAP22 | c.989-345G>T | Intron (SNP) | VAF 49/229 reads (21%) | called by muse, mutect2, varscan2
- ASCC1 | chr10:72096235 G>A | 3'Flank (SNP) | VAF 22/180 reads (12%) | called by muse, mutect2, varscan2
- AWAT2 | c.648-45G>T | Intron (SNP) | VAF 29/251 reads (12%) | called by muse, mutect2, varscan2
- B3GALT5 | c.-523-7281G>T | Intron (SNP) | VAF 79/405 reads (20%) | called by muse, mutect2, varscan2
- C20orf197 | n.509G>C | RNA (SNP) | VAF 74/468 reads (16%) | called by muse, mutect2, varscan2
- CALCB | c.-7G>T | 5'UTR (SNP) | VAF 16/161 reads (10%) | called by muse, mutect2, varscan2
- CD247 | c.-41C>T | 5'UTR (SNP) | VAF 18/320 reads (6%) | called by muse, mutect2
- CD34 | c.973-150T>A | Intron (SNP) | VAF 30/166 reads (18%) | called by muse, mutect2, varscan2
- CEP162 | c.172+1866G>T | Intron (SNP) | VAF 30/157 reads (19%) | catalogued as rs548948924; called by muse, mutect2, varscan2
- CLTRN | c.-20G>T | 5'UTR (SNP) | VAF 27/250 reads (11%) | called by muse, mutect2, varscan2
- COL11A1 | c.898-259del | Intron (DEL) | VAF 40/349 reads (11%) | called by mutect2, pindel, varscan2
- COL5A1 | c.654+7316C>T | Intron (SNP) | VAF 4/49 reads (8%) | called by muse, mutect2
- CORO1B | c.756+321C>A | Intron (SNP) | VAF 16/80 reads (20%) | called by muse, mutect2, varscan2
- DDB1 | c.665-28C>T | Intron (SNP) | VAF 37/493 reads (8%) | called by muse, mutect2
- ESRRB | c.1296+447T>C | Intron (SNP) | VAF 8/52 reads (15%) | called by muse, mutect2, varscan2
- IDO2 | c.-18C>T | 5'UTR (SNP) | VAF 183/474 reads (39%) | called by muse, mutect2, varscan2
- IL1RL1 | c.610+416T>C | Intron (SNP) | VAF 29/90 reads (32%) | called by muse, mutect2, varscan2
- IRF2 | c.87+247G>T | Intron (SNP) | VAF 15/75 reads (20%) | called by muse, mutect2, varscan2
- KCNK9 | c.*35G>T | Intron (SNP) | VAF 371/648 reads (57%) | called by muse, mutect2, varscan2
- KCNMA1 | c.3016+797A>T | Intron (SNP) | VAF 83/219 reads (38%) | called by muse, mutect2, varscan2
- LGSN | c.163+1077G>T | Intron (SNP) | VAF 22/100 reads (22%) | called by mutect2, varscan2
- MAGEC3 | c.1729-45C>A | Intron (SNP) | VAF 4/28 reads (14%) | called by muse, mutect2, varscan2
- MIR296 | chr20:58817702 C>A | 5'Flank (SNP) | VAF 17/84 reads (20%) | called by muse, mutect2, varscan2
- MMGT1 | c.-58G>C | 5'UTR (SNP) | VAF 31/306 reads (10%) | called by muse, mutect2, varscan2
- MMP26 | c.-145+92622C>A | Intron (SNP) | VAF 23/142 reads (16%) | catalogued as rs561325859; called by muse, mutect2, varscan2
- MMP26 | c.-145+92623C>A | Intron (SNP) | VAF 23/142 reads (16%) | catalogued as rs777836233, COSV59033865; called by muse, mutect2, varscan2
- MPDZ | c.*8G>T | 3'UTR (SNP) | VAF 11/72 reads (15%) | called by muse, mutect2, varscan2
- MTBP | c.-21dup | 5'UTR (INS) | VAF 141/318 reads (44%) | called by mutect2, pindel, varscan2
- MTND6P20 | chr8:46843398 G>T | 3'Flank (SNP) | VAF 99/264 reads (38%) | called by muse, mutect2, varscan2
- NDST3 | c.981+28A>T | Intron (SNP) | VAF 89/297 reads (30%) | called by muse, mutect2, varscan2
- NRXN1 | c.772+1063C>T | Intron (SNP) | VAF 34/438 reads (8%) | catalogued as rs184695687; ClinVar: uncertain significance; called by muse, mutect2
- NT5E | c.1360+433G>T | Intron (SNP) | VAF 61/272 reads (22%) | called by muse, mutect2, varscan2
- OPRM1 | c.-245G>T | 5'UTR (SNP) | VAF 8/37 reads (22%) | catalogued as COSV57680903; called by muse, mutect2
- PALM2AKAP2 | c.582+32671C>T | Intron (SNP) | VAF 9/129 reads (7%) | called by muse, mutect2
- PCF11 | c.2092+22G>T | Intron (SNP) | VAF 41/215 reads (19%) | called by muse, mutect2, varscan2
- PGRMC2 | chr4:128287844 C>T | 5'Flank (SNP) | VAF 7/27 reads (26%) | called by muse, mutect2, varscan2
- PKD1 | c.*49C>T | 3'UTR (SNP) | VAF 21/75 reads (28%) | catalogued as rs559096849; called by muse, mutect2, varscan2
- PNCK | c.69-75G>T | Intron (SNP) | VAF 5/13 reads (38%) | catalogued as rs1327520379; called by muse, varscan2
- PNLIPRP1 | c.330+38C>A | Intron (SNP) | VAF 41/336 reads (12%) | called by muse, mutect2, varscan2
- PNLIPRP3 | c.-22G>A | 5'UTR (SNP) | VAF 15/208 reads (7%) | catalogued as rs368300426; called by muse, mutect2
- RCOR2 | c.1258-50G>A | Intron (SNP) | VAF 43/220 reads (20%) | catalogued as rs772977008; called by muse, mutect2, varscan2
- RTL8B | c.-1G>T | 5'UTR (SNP) | VAF 7/38 reads (18%) | catalogued as rs772515646; called by muse, varscan2
- RYR2 | c.14656-25G>A | Intron (SNP) | VAF 31/148 reads (21%) | catalogued as rs376695688; called by muse, mutect2, varscan2
- SLC25A13 | c.*722A>G | 3'UTR (SNP) | VAF 151/722 reads (21%) | called by muse, mutect2, varscan2
- SND1 | c.1779+6691G>T | Intron (SNP) | VAF 38/129 reads (29%) | called by muse, mutect2
- SSPOP | n.3738G>T | RNA (SNP) | VAF 55/219 reads (25%) | called by muse, mutect2, varscan2
- SSPOP | n.8450C>A | RNA (SNP) | VAF 12/89 reads (13%) | called by muse, mutect2, varscan2
- SSTR5-AS1 | n.1222G>A | RNA (SNP) | VAF 18/93 reads (19%) | called by muse, mutect2, varscan2
- TMCO1 | c.*2254G>A | 3'UTR (SNP) | VAF 43/179 reads (24%) | called by muse, mutect2, varscan2
- TMEM70 | c.*818G>C | 3'UTR (SNP) | VAF 101/187 reads (54%) | called by muse, mutect2, varscan2
- TTBK2 | c.823-6535T>C | Intron (SNP) | VAF 14/246 reads (6%) | called by muse, mutect2
- XKR4 | c.806+58308G>T | Intron (SNP) | VAF 28/478 reads (6%) | called by muse, mutect2
- ZNF30 | c.-37C>T | 5'UTR (SNP) | VAF 45/166 reads (27%) | called by muse, mutect2, varscan2
